Somatic mutation profile of tumor specimen C3N-03670-01 (aliquot CPT0246840006) from CPTAC case C3N-03670, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 60.3 years (22,035 days).
Specimen C3N-03670-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 337ba993-86e5-47e4-8a08-1859c8f3f1be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03670-31 (Blood Derived Normal), aliquot CPT0246880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/487ee7b8-6583-452f-8979-3ad8b309bf46

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Nonsense Mutation 2, 5'Flank 1, 3'UTR 1, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP3K21 | c.1663C>T p.R555* | Nonsense Mutation (SNP) | VAF 9/198 reads (5%) | catalogued as rs1182227655; called by muse, mutect2
- NTSR2 | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV60990455; called by muse, mutect2
- POC1A | c.498C>A p.D166E | Missense Mutation (SNP) | VAF 13/327 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1200549706; called by muse, mutect2
- RORB | c.214C>T p.R72C (on ENST00000396204 / NM_001365023.1; = p.R61C on NM_006914.4) | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268898925; called by muse, mutect2
- TCEA2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 17/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568253300, COSV58658359; called by muse, mutect2
- ZNF214 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.763); catalogued as COSV53483125; called by muse, mutect2
- BTBD7 | c.2245G>A p.D749N | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.398); called by muse, mutect2
- FANCG | c.1393C>T p.Q465* | Nonsense Mutation (SNP) | VAF 17/440 reads (4%) | called by muse, mutect2
- MRAP | c.107-7C>T | Splice Region (SNP) | VAF 24/524 reads (5%) | called by muse, mutect2
- PDX1 | c.265C>A p.Q89K | Missense Mutation (SNP) | VAF 35/523 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- PTPRN | c.868A>G p.R290G | Missense Mutation (SNP) | VAF 50/511 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.036); called by muse, mutect2
- SLC8A1 | c.863A>C p.E288A | Missense Mutation (SNP) | VAF 10/269 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.198); called by muse, mutect2
- TUBA3C | c.888C>T p.F296= | Silent (SNP) | VAF 17/283 reads (6%) | catalogued as rs778833077; called by muse, mutect2
- CARMIL1 | chr6:25279183 C>A | 5'Flank (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- MUC2 | c.*3G>A | 3'UTR (SNP) | VAF 6/142 reads (4%) | catalogued as rs766530819; called by muse, mutect2
